Surgical pathology report (de-identified scan), TCGA case TCGA-S9-A7R1, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Dept of Neurosurgery at University of Heidelberg, specimen TCGA-S9-A7R1-01A (Primary Tumor).

ICD 8-3
Oligodendroglioma, grade II 945013
Site CCF Brain, supratentorial NOS C71.0
1st Brain NOS C71.9
Q19127113

Untranslated original report
is housed at the BCR.

12/19/05
Oligodendroglioma WHO grade II

Source: NCI Genomic Data Commons file 12e78769-3c3f-4e9f-a1d1-0fa835bcc3fa (TCGA-S9-A7R1.7E6FECAF-5861-4BE0-B867-17AEC6FF9E0B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).